CPTAC case C3N-00682 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/815c4ffb-2fb9-4460-8196-6636be74f6a6

Demographics
Sex at birth: male; Race: white; Year of birth: 1948; Vital status: Dead; Days to death: 26 days; Year of death: 2018; Country of birth: Poland.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.1 years (25,252 days); Year of diagnosis: 2018; Days to last known disease status: 26 days; Days to last follow up: 26 days.

Follow-up (1 entry)
- Days to follow up: 26 days; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 67 kg; Height: 179 cm; BMI: 20.

Exposures
- Tobacco smoking status: Current Smoker.

Biospecimens (5 samples)
- Samples C3N-00682-50, C3N-00682-51, C3N-00682-52 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3N-00682-54, C3N-00682-55 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 10 days; Time between excision and freezing: 124 minutes; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
